Somatic mutation profile of tumor specimen C3N-01766-04 (aliquot CPT0226810006) from CPTAC case C3N-01766, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 63.5 years (23,195 days).
Specimen C3N-01766-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afb11aee-b1af-4714-9096-ac1ca39a033f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01766-31 (Blood Derived Normal), aliquot CPT0226850002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61647088-14de-470d-bd47-1a0e33612cf7

The open-access MAF lists 56 somatic variants for this specimen: 39 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Nonsense Mutation 4, Intron 4, Frame Shift Ins 2, 5'UTR 2, RNA 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.204C>G p.Y68* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | hotspot (GDC flag); catalogued as rs773176120, CM110140, COSV64297713; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 135/472 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.4409C>T p.T1470M | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs146348192, COSV60619860; called by muse, mutect2
- ADGRD1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs144030317; called by muse, mutect2
- ANKRD52 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 23/556 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); catalogued as rs1386191599, COSV57287457; called by muse, mutect2
- ASIC4 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs199606156; called by muse, mutect2, varscan2
- C1QA | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 154/713 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs774674695, COSV65889364; called by muse, mutect2, varscan2
- CFAP57 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777001077; called by muse, mutect2, varscan2
- DNAH17 | c.11379C>G p.I3793M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as rs367920298; called by muse, mutect2
- DPP10 | c.1559T>C p.M520T | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV59687999; called by muse, mutect2, varscan2
- FPR3 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 9/119 reads (8%) | catalogued as rs146700831; called by muse, mutect2
- MYO5B | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 49/516 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755378266, COSV53216604; called by muse, mutect2
- NKPD1 | c.2045G>A p.G682D | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.523); catalogued as rs764804362; called by muse, mutect2, varscan2
- OR52A5 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs777358733, COSV56615982; called by muse, mutect2, varscan2
- PCDHA7 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 54/642 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.341); catalogued as rs781842437, COSV65344578; called by muse, mutect2
- PKD1L1 | c.1849G>A p.G617S | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs116782098, COSV99221513; called by muse, mutect2
- RBP4 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 97/739 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370579379; called by muse, mutect2, varscan2
- SCUBE3 | c.2480G>A p.G827D | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs150725422; called by muse, mutect2, varscan2
- SORCS2 | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777090653, COSV61172934; called by muse, mutect2
- STPG3 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs112726953, COSV100546974; called by muse, mutect2, varscan2
- TTN | c.14395C>T p.R4799* (on ENST00000591111; = p.R3872* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as rs1057518470, COSV59932123; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC80 | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs373287604; called by muse, mutect2, varscan2
- UNC80 | c.4429G>A p.V1477I | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs994979037; called by muse, mutect2, varscan2
- WDFY4 | c.5608G>A p.A1870T | Missense Mutation (SNP) | VAF 117/515 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs904057590, COSV55426627, COSV55427316; called by muse, mutect2, varscan2
- ZFHX2 | c.5366G>A p.R1789Q | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs761920427; called by muse, mutect2, varscan2
- ZNF311 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 66/452 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs779080825; called by muse, mutect2, varscan2
- ARHGAP23 | c.3218C>A p.T1073K | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2
- ARID1A | c.1498dup p.Y500Lfs*123 | Frame Shift Ins (INS) | VAF 132/697 reads (19%) | called by mutect2, pindel, varscan2
- CSF2RA | c.1104_1112del p.D368_H370del | In Frame Del (DEL) | VAF 49/372 reads (13%) | called by mutect2, pindel, varscan2
- CWC22 | c.423G>T p.M141I | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, varscan2
- LRRC31 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- SGPP1 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC16A7 | c.641C>A p.T214K | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC35E2B | c.1148C>A p.A383E | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.022); called by muse, mutect2
- SOX17 | c.403_404dup p.K136Tfs*11 | Frame Shift Ins (INS) | VAF 22/154 reads (14%) | called by mutect2, pindel, varscan2
- STK31 | c.2305A>T p.K769* | Nonsense Mutation (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2
- SYTL4 | c.771A>G p.I257M | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- TRABD2A | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.229); called by muse, mutect2
- C19orf81 | c.498C>T p.D166= | Silent (SNP) | VAF 23/185 reads (12%) | called by muse, mutect2, varscan2
- CDH22 | c.1812C>T p.S604= | Silent (SNP) | VAF 52/399 reads (13%) | catalogued as rs372950957; called by muse, mutect2, varscan2
- EFL1 | c.2469C>T p.I823= | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as COSV51608306; called by muse, mutect2, varscan2
- FAT1 | c.13707C>T p.D4569= | Silent (SNP) | VAF 10/145 reads (7%) | catalogued as rs745595921, COSV71674460; called by muse, mutect2
- FLNA | c.5715G>A p.P1905= (on ENST00000369850 / NM_001110556.2; = p.P1897= on NM_001456.3) | Silent (SNP) | VAF 27/170 reads (16%) | catalogued as rs367674709; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- GPR101 | c.843C>T p.D281= | Silent (SNP) | VAF 38/270 reads (14%) | catalogued as rs747610112, COSV53240282; called by muse, mutect2, varscan2
- KIAA1755 | c.3414C>T p.D1138= | Silent (SNP) | VAF 30/283 reads (11%) | catalogued as rs758714376; called by muse, mutect2, varscan2
- SPG11 | c.5757A>T p.S1919= | Silent (SNP) | VAF 72/456 reads (16%) | called by muse, mutect2, varscan2
- ZNF646 | c.4044C>T p.H1348= | Silent (SNP) | VAF 21/240 reads (9%) | called by muse, mutect2
- A2ML1 | c.1477-199C>T | Intron (SNP) | VAF 17/213 reads (8%) | called by muse, mutect2
- CD7 | c.612+45C>G | Intron (SNP) | VAF 75/507 reads (15%) | called by muse, mutect2, varscan2
- KCTD7 | c.-72C>G | 5'UTR (SNP) | VAF 51/210 reads (24%) | called by muse, mutect2, varscan2
- LINC01551 | n.1255-5426G>A | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as rs953571778; called by mutect2, varscan2
- MST1L | n.469C>T | RNA (SNP) | VAF 18/102 reads (18%) | catalogued as rs201680871; called by muse, mutect2, varscan2
- MYF6 | c.*29G>A | 3'UTR (SNP) | VAF 58/286 reads (20%) | catalogued as COSV99953004; called by muse, mutect2, varscan2
- SLBP | c.-93C>T | 5'UTR (SNP) | VAF 11/62 reads (18%) | catalogued as rs1355413670; called by muse, mutect2, varscan2
- SRPK2 | c.71+82130A>C | Intron (SNP) | VAF 40/182 reads (22%) | catalogued as rs1336871530; called by muse, mutect2, varscan2
